Gene-level copy-number profile of tumor specimen TCGA-D9-A6EC-06A from TCGA case TCGA-D9-A6EC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 60.5 years (22,106 days).
Specimen TCGA-D9-A6EC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.10a644e5-e853-4fec-b308-479184062562.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D9-A6EC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bf912f42-3ad6-4371-9d27-3081f8060ca9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 322; copy number 2: 14,907; copy number 3: 15,731; copy number 4: 23,223; copy number 5: 2,684; copy number 6: 1,594; copy number 7: 581; copy number 8: 644; copy number 9: 41; copy number 10: 27; copy number 12: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D9-A6EC-06A-11D-A30W-01): tumor purity 0.95, ploidy 3.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:123,882,920–124,254,364, 22 genes: TMEM225, OR8D4, OR4D5, OR6T1, OR10S1, OR10G6, OR10G5P, OR10G4, OR10G9, OR10G8, OR10G7, OR10D5P, OR10D4P, OR10N1P, VWA5A, OR10D1P, OR10D3, OR8F1P, OR8G3P, OR8G2P, OR8G7P, OR8G1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 108 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:66,997,168–71,583,989, 39 genes, copy number 12 (within-gene range 6–12): AC020655.1, KBTBD8, MIR4272, AC114401.1, SUCLG2, NDUFB4P1, SUCLG2-AS1, TAFA1, COPS8P2, AC107626.1, AC104167.1, AC096922.1, PSMC1P1, TAFA4, RNA5SP135, EOGT, AC109587.1, TMF1, MIR3136, UBA3, ARL6IP5, LMOD3, FRMD4B, RBM43P1, AC099328.1, AC099328.2, AC104445.1, MITF, RN7SL418P, SAMMSON, AC139700.1, UQCRHP4, MDFIC2, AC104633.1, AC104633.2, COX6CP6, HMGB1P36, RNU6-281P, FOXP1.
- chr3:71,289,769–71,305,853, 1 gene, copy number 12: FOXP1-AS1.
- chr12:45,215,987–47,079,959, 26 genes, copy number 10 (within-gene range 5–10): ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1, AMIGO2.
- chr12:47,135,498–47,138,370, 1 gene, copy number 10: IFITM3P6.
- chr12:67,065,018–68,805,479, 41 genes, copy number 9: AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3.

Autosomal genes at a single copy (total copy number 1): 321. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
